Surgical pathology report (de-identified scan), TCGA case TCGA-KM-A7QA, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-A7QA-01C (Primary Tumor).

[page 1 of 3]
Patient Results

Page 1 of 3

Gender: Male	Birth Date:	Admit Date:
Attending:	Admit Protocol:	Age:
		Location:

Surgical Pathology [Order ID:	Final Results
-------------------------------	---------------

Surgical Pathology
CASE NUMBER:
DIAGNOSIS:

Final

1. Portion of adrenal, left, resection: Adrenal gland, no tumor seen.
2. Kidney, left, radical nephrectomy: Renal cell carcinoma, chromophobe type, Paner grade 2; vascular invasion present. Vascular and ureteral margins are free of tumor. See Note.
3. Lymph node, para and interaortic, resection: Nineteen lymph nodes, no tumor seen (0/19).

ICD-O-3
Carcinoma, renal cell
chromophobe type 831713
Site @ Kidney NOS
264.9
JW 9/24/13

NOTE: Please refer to the following for staging information.

CAP cancer checklist:

KIDNEY: Nephrectomy, Radical

Procedure: Radical nephrectomy

Specimen Laterality: Left

Tumor Site: Upper pole

Tumor Size (largest tumor if multiple): Greatest dimension: 8.0 cm,

Additional dimensions: 7.0 x 4.0 cm

Tumor Focality: Unifocal,

Macroscopic Extent of Tumor: Tumor limited to kidney. No capsular or perinephric fat invasion identified.

Histologic Type: Chromophobe renal cell carcinoma

Sarcomatoid Features: Not identified

Tumor Necrosis (any amount): Not identified

Histologic Grade: Other (specify): Paner grade 2

Microscopic Tumor Extension: Tumor limited to kidney

Margins: Margins uninvolved by invasive carcinoma

Lymph-Vascular Invasion: Present

Pathologic Staging (pTNM)

Primary Tumor (pT):

pT2a: Tumor more than 7 cm but less than or equal to 10 cm in greatest dimension, limited to the kidney

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined, Specify: 19

Number of Lymph Nodes Involved, Specify: 0

Distant Metastasis (pM): Not applicable

Pathologic Findings in Nonneoplastic Kidney: None identified

Other Tumors and/or Tumor-like Lesions: None

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

[page 2 of 3]
Gender: Male		Birth Date:	Admit Protocol:
Admit Protocol:		Admit Protocol:	Age:
			Location:

Surgical Pathology [OrderID:	Final Results
------------------------------	---------------

CLINICAL INFORMATION: Brief Clinical History: left renal tumor
Specimen Taken For Protocol:
01 - Yes Allocate Order to Protocol:

PROCEDURE: Operative Findings: left kidney and retroperitoneal lymph nodes removed
Post-Operative Diagnosis: left renal tumor Pre-Operative Diagnosis: left renal tumor

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT, Portion of Gland
2. KIDNEY, LEFT, Portion of gland
3. LYMPH NODES, Para and Inter Aortic Caval
GROSS DESCRIPTION:

Received at Surgical Pathology is a formalin-filled container labeled with the patient's name, medical record number, date of birth, and further designated as:

1. "Portion left adrenal gland". The specimen consists of an adrenal gland segment measuring 4 x 1 x 1 cm. There is no palpable nodule within the specimen. The specimen is serially sectioned and submitted entirely in 5 white cassettes labeled as 1A-1E.
2. "Left kidney". The specimen consists of an intact kidney with attached perinephric fat measuring 16 x 9 x 6 cm and weighing 343 grams collectively. The isolated kidney measures 14.8 x 8.4 x 5.5 cm and weighs 305 grams. The perirenal fat capsule is inked with black. Extending from the renal pelvis are 2 ureters. The upper ureter is 5 cm in length and 0.4 cm in diameter. The lower ureter is 8 cm in length and 0.5 cm in diameter. Renal vein is 0.5 cm in length and 0.6 cm in diameter and the upper renal artery branch is 1.8 cm in length and 0.5 cm in diameter, the lower one is 1.0 cm in length and 0.4 cm in diameter. The perirenal fat layer is stripped, revealing the intact renal capsule, which is inked blue. Tumor does not extend to the ureters, arteries, and vein and is not present at the resection margin. The kidney is bisected, revealing an 8 x 7 x 4 cm circumscribed solid pink mass without hemorrhage and necrosis in the upper pole of the left kidney. It is 1.0 cm from the renal hilum. The mass is confined by the renal capsule and does not invade the perinephric fat. The uninvolved renal parenchyma is tan-brown with a well-defined cortical medullary junction and orderly cortical striations and medullary rays. The pelvis and calyx appear smooth. There are no lymph nodes or stones identified. Gross photographs are taken. In the upper pole, there is a 0.5-cm erythematous area, presumably the core biopsy site. Representative sections are submitted as follows:
- A-D - relationship between tumor and the renal capsule
- E-G - relationship between tumor and the pelvis
- H - relationship between tumor and normal kidney tissue
- I-O, X-Z, AA, BB - representative sections of the tumor
- R - the upper ureter margin

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

JobID:

Requested By:

Do not file in Medical Record

[page 3 of 3]
Gender: Male	Birth Date:	Admit Protocol:
Admit Protocol:	Admit Protocol:	Location:

Surgical Pathology (OrderID:	Final Results
-------------------------------------	----------------------

S - lower ureter margin
T - resection margin from the two renal artery branches.
U - resection margin of the vein
V - kidney parenchyma where the core biopsy is done
W - the perirenal fat.

3. "Para and interaortic lymph node". The specimen consists of a fibroadipose tissue fragment measuring 4 x 3 x 3 cm. 16 candidate lymph nodes are appreciated ranging from 0.4 to 1.0 cm in greatest dimension. They are submitted entirely in 5 white cassettes labeled as

Gross Description dictated by

No consultants
Accessioned:
Final Report Signed Out:

<Resident Signature>
PhD, CLINICAL RESIDENT

<Sign Out Dr. Signature>
MD, ATTENDING STAFF PATHOLOGIST

Date Report Signed:

Source: NCI Genomic Data Commons file eb46c014-288e-49cf-84fa-90d5d3b3bfb9 (TCGA-KM-A7QA.47C0AD9A-A83E-45BD-ACF3-09F97D680BEC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).